Somatic mutation profile of tumor specimen ALCH-B1S5-TTP1-A (aliquot ALCH-B1S5-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1S5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,263 days).
Specimen ALCH-B1S5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4315b34-f73b-47bd-90b4-6cc9d1bbfaf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1S5-NB1-A (Blood Derived Normal), aliquot ALCH-B1S5-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de4657eb-e927-4ded-b74f-6f045d4ef2f1

The open-access MAF lists 94 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, RNA 5, Nonsense Mutation 4, Intron 3, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 44/492 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 34/307 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 22/237 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ACAN | c.4328C>A p.P1443H | Missense Mutation (SNP) | VAF 34/716 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as COSV61361656; called by muse, mutect2
- COL22A1 | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100276104, COSV57362005; called by muse, mutect2, varscan2
- CUX1 | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1349024125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF12L1 | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100948340; called by muse, mutect2
- DLGAP3 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 8/237 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs868322976; called by muse, mutect2
- EPHA6 | c.1923G>T p.Q641H (on ENST00000389672 / NM_001080448.3; = p.Q33H on NM_173655.4) | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV67560959; called by muse, mutect2
- KCNK13 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV56418513; called by muse, mutect2
- MS4A2 | c.696G>T p.L232F | Missense Mutation (SNP) | VAF 33/579 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54012131; called by muse, mutect2
- NCKAP1L | c.3244C>G p.R1082G | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53203936, COSV53214203; called by muse, mutect2
- NCKAP5 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58450411; called by muse, mutect2
- OPN4 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV54115527; called by muse, mutect2
- PCDHB5 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 31/755 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as rs782294917, COSV99167563; called by muse, mutect2
- PCDHGB2 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 36/690 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99528897; called by muse, mutect2
- PRDM9 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 52/613 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV57005795, COSV99691139; called by muse, mutect2
- PTBP2 | c.1328C>T p.P443L (on ENST00000426398 / NM_001300986.2; = p.P435L on NM_021190.4) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV64624478; called by muse, mutect2
- SCAPER | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs968279978; called by muse, mutect2
- SDK2 | c.5375C>T p.A1792V | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs541836618, COSV66196300; called by muse, mutect2
- SEMA6D | c.2795C>A p.P932H (on ENST00000316364 / NM_153618.2; = p.P870H on NM_020858.2) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100317611; called by muse, mutect2
- TIMD4 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV50859360; called by muse, mutect2
- TYR | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54474168; called by muse, mutect2
- ZFPM2 | c.1465G>T p.G489W | Missense Mutation (SNP) | VAF 34/794 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65874434; called by muse, mutect2
- AC126283.2 | c.1230A>T p.E410D | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.074); called by muse, mutect2
- ACKR1 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2
- ANKFN1 | c.2897G>T p.R966L (on ENST00000653862; = p.R819L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- C10orf71 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C6orf163 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- CAPZA1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- COL13A1 | c.1079C>A p.S360Y (on ENST00000398978 / NM_001130103.2; = p.S303Y on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.155); called by muse, mutect2
- COPG1 | c.2158+1G>T p.X720_splice | Splice Site (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- CYP11B1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- DNAAF3 | c.992G>T p.G331V (on ENST00000524407 / NM_001256715.2; = p.G378V on NM_178837.4) | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- DNAH5 | c.10738G>T p.G3580C | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FHOD3 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.063); called by muse, mutect2
- GABRG2 | c.1249-5C>A | Splice Region (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- GUCY2C | c.512T>C p.L171S | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- GUCY2F | c.2674G>T p.G892C | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- HIPK3 | c.1806C>G p.H602Q | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.024); called by muse, mutect2
- KCNC4 | c.1018C>A p.R340S | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KIF4A | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- L1CAM | c.1503T>A p.N501K | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMO7 | c.2608A>T p.T870S (on ENST00000357063; = p.T551S on NM_005358.5) | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- LRIG2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- LRRN3 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- MXRA5 | c.5822T>A p.V1941D | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NCAM1 | c.2420C>A p.T807K (on ENST00000316851 / NM_181351.5; = p.T797K on NM_000615.7) | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- OR4F15 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PCDHGA10 | c.316T>A p.C106S | Missense Mutation (SNP) | VAF 15/443 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT8 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- SEC31A | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- SLITRK4 | c.2146G>T p.G716* | Nonsense Mutation (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- STRA8 | c.897T>A p.C299* (on ENST00000275764; = p.C277* on NM_182489.2) | Nonsense Mutation (SNP) | VAF 42/334 reads (13%) | called by muse, mutect2, varscan2
- STRA8 | c.898G>A p.A300T (on ENST00000275764; = p.A278T on NM_182489.2) | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TECTA | c.5707G>T p.D1903Y | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TIAM2 | c.3615T>A p.C1205* | Nonsense Mutation (SNP) | VAF 14/422 reads (3%) | called by muse, mutect2
- TMEM236 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 40/907 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TTN | c.44425C>A p.P14809T (on ENST00000591111; = p.P7385T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.44424T>A p.D14808E (on ENST00000591111; = p.D7384E on NM_003319.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | PolyPhen benign (0.274); called by mutect2, varscan2
- UGT2A2 | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.909); called by muse, mutect2
- VSTM2B | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.033); called by muse, mutect2
- WDR88 | c.1304C>A p.T435N | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- ZNF207 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZNF623 | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF649 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2
- ALOX12B | c.849C>A p.I283= | Silent (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- ASGR2 | c.118T>C p.L40= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- CEMIP | c.2944C>A p.R982= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- DIO2 | c.600G>A p.E200= | Silent (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- ETNPPL | c.1278G>C p.V426= | Silent (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2
- IGKV2D-29 | c.210G>A p.Q70= | Silent (SNP) | VAF 28/508 reads (6%) | catalogued as rs751457848; called by muse, mutect2
- MAGEE1 | c.1488T>A p.A496= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- MARCHF8 | c.726A>T p.P242= | Silent (SNP) | VAF 16/377 reads (4%) | called by muse, mutect2
- MFN1 | c.1014A>G p.E338= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- NTM | c.438C>A p.S146= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- OR8B8 | c.468C>A p.A156= | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- PKHD1 | c.10083C>A p.A3361= | Silent (SNP) | VAF 13/328 reads (4%) | called by muse, mutect2
- ROBO2 | c.2868A>T p.P956= | Silent (SNP) | VAF 20/555 reads (4%) | called by muse, mutect2
- SLC9A9 | c.804C>A p.A268= | Silent (SNP) | VAF 18/338 reads (5%) | catalogued as COSV57246308; called by muse, mutect2
- SLITRK2 | c.2052C>A p.V684= | Silent (SNP) | VAF 21/375 reads (6%) | called by muse, mutect2
- SNRNP200 | c.867A>G p.V289= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- SYPL1 | c.381G>T p.L127= | Silent (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- THSD7B | c.1791C>A p.P597= | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as COSV55734176; called by muse, mutect2
- UMOD | c.1383G>T p.A461= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- AL033381.1 | n.466C>A | RNA (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- DCDC2 | c.348+301G>T | Intron (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- HSP90AA4P | n.1033C>A | RNA (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- ISLR2 | chr15:74129007 C>A | 5'Flank (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- MIR1297 | n.57G>T | RNA (SNP) | VAF 20/315 reads (6%) | called by muse, mutect2
- NPIPB1P | n.904C>A | RNA (SNP) | VAF 21/630 reads (3%) | called by muse, mutect2
- SPEF2 | c.4448-3069C>A | Intron (SNP) | VAF 32/432 reads (7%) | called by muse, mutect2
- SSPOP | n.10853del | RNA (DEL) | VAF 14/140 reads (10%) | called by mutect2, varscan2
- ZEB2 | c.73+4910G>A | Intron (SNP) | VAF 19/347 reads (5%) | catalogued as rs908589210; called by muse, mutect2
